Somatic mutation profile of cancer-model specimen HCM-BROD-0791-C43-85O (Adherent Cell Line, passage 22; aliquot HCM-BROD-0791-C43-85O-01D-A87L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0791-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.0 years (22,298 days).
Specimen HCM-BROD-0791-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 22.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deeeb381-2fea-4090-bf6e-9656ad767c6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0791-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0791-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b75e7802-5ceb-442a-8c3e-84c50e2e5a41

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 200/200 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APLNR | c.842G>C p.C281S | Missense Mutation (SNP) | VAF 240/468 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57242127; called by muse, mutect2, varscan2
- ATP10A | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.144); catalogued as COSV100791076, COSV63517530; called by muse, varscan2
- CCL1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 175/369 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs559669850; called by muse, varscan2
- CFAP46 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs533730270, COSV63949557; called by muse, mutect2, varscan2
- DMBT1 | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV57563354; called by muse, mutect2, varscan2
- DMD | c.10888C>G p.R3630G | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as CM098464, COSV100627284; called by muse, mutect2
- FBXO24 | c.403G>A p.G135S (on ENST00000241071 / NM_033506.3; = p.G173S on NM_012172.5) | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200639966, COSV99575556; called by muse, mutect2
- HNF4G | c.1136del p.P379Hfs*11 (on ENST00000354370 / NM_001330561.2; = p.P426Hfs*11 on NM_004133.5) | Frame Shift Del (DEL) | VAF 138/356 reads (39%) | catalogued as COSV62966825; called by mutect2, pindel, varscan2
- SLC2A13 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 297/592 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); catalogued as rs1402944975; called by muse, mutect2, varscan2
- SLC30A1 | c.210C>G p.N70K | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100879170; called by muse, mutect2, varscan2
- VCAN | c.10109C>A p.S3370Y | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54114125; called by muse, mutect2, varscan2
- VPS53 | c.817C>A p.Q273K (on ENST00000571805 / NM_001366253.2; = p.Q244K on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.216); catalogued as rs1156924460; called by muse, mutect2, varscan2
- VTN | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 219/484 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs113538498; called by muse, mutect2, varscan2
- ZNF423 | c.2814C>G p.H938Q (on ENST00000563137 / NM_001379286.1; = p.H930Q on NM_015069.4) | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV52178658; called by muse, mutect2
- BICRAL | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 198/426 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CANT1 | c.784T>A p.W262R | Missense Mutation (SNP) | VAF 48/601 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC186 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CD209 | c.1023G>C p.Q341H | Missense Mutation (SNP) | VAF 155/299 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD44 | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 124/192 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- CPPED1 | c.338_339insA p.A114Gfs*16 | Frame Shift Ins (INS) | VAF 114/411 reads (28%) | called by mutect2, pindel, varscan2
- CRISP3 | c.217A>T p.I73F (on ENST00000371159 / NM_001368123.1; = p.I55F on NM_006061.4) | Missense Mutation (SNP) | VAF 186/373 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.2011G>T p.V671F (on ENST00000520002; = p.V670F on NM_033225.6) | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- D2HGDH | c.820C>G p.P274A | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPP3 | c.1815del p.V606* | Frame Shift Del (DEL) | VAF 98/269 reads (36%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.959T>A p.V320D (on ENST00000528054; = p.V289D on NM_019839.5) | Missense Mutation (SNP) | VAF 246/491 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MAPK8 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR1H2 | c.215A>T p.K72M | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDLIM2 | c.540G>A p.Q180= (on ENST00000397760; = p.Q430= on NM_021630.6) | Splice Region (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- PLCD3 | c.2276A>G p.K759R | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAB27A | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 118/137 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SLC15A1 | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SPEM3 | c.2560G>C p.V854L | Missense Mutation (SNP) | VAF 190/191 reads (99%) | SIFT tolerated (0.23); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SYT1 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2
- TMEM120A | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 16/421 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF532 | c.1916G>T p.S639I | Missense Mutation (SNP) | VAF 199/378 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by mutect2, varscan2
- ASMT | c.510C>T p.S170= | Silent (SNP) | VAF 49/620 reads (8%) | catalogued as rs1382548741; called by muse, mutect2
- CBX4 | c.645C>A p.A215= | Silent (SNP) | VAF 413/827 reads (50%) | called by muse, mutect2, varscan2
- DAPK1 | c.2901G>A p.E967= | Silent (SNP) | VAF 130/304 reads (43%) | called by muse, mutect2, varscan2
- DNAH12 | c.8280T>A p.I2760= (on ENST00000351747; = p.I3628= on NM_001366028.2) | Silent (SNP) | VAF 110/222 reads (50%) | called by muse, mutect2, varscan2
- GJB6 | c.573T>C p.F191= | Silent (SNP) | VAF 17/360 reads (5%) | called by muse, mutect2
- LTB4R2 | c.960C>A p.V320= (on ENST00000528054; = p.V289= on NM_019839.5) | Silent (SNP) | VAF 247/492 reads (50%) | called by muse, mutect2, varscan2
- MAP3K10 | c.1764A>C p.S588= | Silent (SNP) | VAF 38/289 reads (13%) | called by muse, mutect2, varscan2
- MPPED2 | c.189C>T p.I63= | Silent (SNP) | VAF 88/278 reads (32%) | catalogued as COSV63900666; called by muse, mutect2, varscan2
- OR2G6 | c.744C>G p.V248= | Silent (SNP) | VAF 57/385 reads (15%) | called by muse, mutect2, varscan2
- PLCB4 | c.1797C>T p.V599= | Silent (SNP) | VAF 30/242 reads (12%) | catalogued as rs778436381; ClinVar: benign; called by muse, mutect2, varscan2
- RNF214 | c.1518C>T p.S506= | Silent (SNP) | VAF 302/615 reads (49%) | called by muse, mutect2, varscan2
- USH2A | c.5836C>A p.R1946= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as CM104085; called by muse, mutect2, varscan2
